Gene-level copy-number profile of tumor specimen TCGA-VS-A950-01A from TCGA case TCGA-VS-A950, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 42.1 years (15,365 days).
Specimen TCGA-VS-A950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.56a6ef36-33c4-4b71-80b7-6ff51f05b8c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A950-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd256dba-354e-4e13-949d-436766026381

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 3,344; copy number 3: 21,943; copy number 4: 22,941; copy number 5: 2,481; copy number 6: 6,765; copy number 7: 863; copy number 8: 58; copy number 9: 379; copy number 10: 1,037.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A950-01A-11D-A42N-01): tumor purity 0.46, ploidy 3.95, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–140,992,659, 2 genes: LRRC57P1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,416 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,855,739–198,222,513, 937 genes, copy number 10 (broad region; genes not listed).
- chr15:80,059,568–94,726,519, 378 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr15:94,855,586–94,857,011, 1 gene, copy number 9: AC107976.1.
- chr15:98,038,571–98,293,199, 1 gene, copy number 10 (within-gene range 8–10): AC022523.1.
- chr15:98,282,075–101,933,350, 99 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
